CCDI case PBBRVH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9099e588-18cc-416d-9c93-246349b3af92

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: ICD-O-3 morphology code: 9401/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.0 years (5,116 days).

Biospecimens (3 samples)
- Sample 0DF6VB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DF6VH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DF6VL: Tissue type: Tumor; Specimen type: Solid Tissue.
